Surgical pathology report (de-identified scan), TCGA case TCGA-34-8455, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-8455-01A (Primary Tumor).

FINAL DIAGNOSIS:**Summary Statement**

The left upper lobe demonstrates a 7.8 cm squamous cell carcinoma extending into the left lower lobe and associated with grossly identified four tumor nodules of morphologically similar squamous cell carcinoma measuring up to 0.4 cm in diameter. There is no evidence of visceral pleural invasion. All sampled lymph nodes are benign (see Comment).

PART 1: LYMPH NODE, LEVEL 5, BIOPSY -

THREE (3) FRAGMENTS OF BENIGN LYMPH NODE.

PART 2: LYMPH NODE, INFERIOR PULMONARY LIGAMENT, BIOPSY -

ONE (1) LYMPH NODE.

PART 3: BONE, SIXTH (6TH) RIB, RESECTION -

UNREMARKABLE BONE AND BONE MARROW.

PART 4: LYMPH NODE, LEVEL 10, BIOPSY -

ONE (1) BENIGN LYMPH NODE.

PART 5: LYMPH NODE, LEVEL 11, BIOPSY -

ONE (1) BENIGN LYMPH NODE.

PART 6: LYMPH NODE, LEVEL 10, BIOPSY -

FOUR (4) FRAGMENTS OF BENIGN LYMPH NODE.

PART 7: LYMPH NODE, LEVEL 11, BIOPSY -

ONE (1) BENIGN LYMPH NODE.

PART 8: LYMPH NODE, LEVEL 10, BIOPSY -

A. UNREMARKABLE FIBROADIPOSE TISSUE.

B. NO LYMPHOID TISSUE IDENTIFIED.

PART 9: LYMPH NODE, LEVEL 10 NEAR INFERIOR VEIN, BIOPSY -

ONE (1) BENIGN LYMPH NODE.

PART 10: LYMPH NODE, LEVEL 11 NEAR UPPER LOBE PULMONARY ARTERY, BIOPSY -

ONE (1) BENIGN LYMPH NODE.

PART 11: TISSUE NEAR LEVEL 12, BIOPSY -

FIBROADIPOSE TISSUE WITH MILD CHRONIC INFLAMMATION, MOST SUGGESTIVE OF SCAR.

PART 12: LYMPH NODE, LEVEL 11 NEAR DEEP FISSURE, BIOPSY -

SIX (6) FRAGMENTS OF BENIGN LYMPH NODE.

PART 13: LYMPH NODE, TISSUE NEAR INFERIOR FISSURE, BIOPSY -

UNREMARKABLE FIBROADIPOSE TISSUE.

PART 14: LYMPH NODE, LEVEL 12, BIOPSY -

ONE (1) BENIGN LYMPH NODE.

PART 15: LUNG, LFT UPPER LOBE, LOBECTOMY -

A. SQUAMOUS CELL CARCINOMA (7.8 CM IN DIAMETER) ASSOCIATED WITH FOUR GROSSLY IDENTIFIED TUMOR NODULES OF MORPHOLOGICALLY SIMILAR SQUAMOUS CELL CARCINOMA. MILD LYMPHOCYTIC HOST RESPONSE. NO EVIDENCE OF VISCERAL PLEURAL INVASION. FOUR (4) FRAGMENTS OF BENIGN N1 LYMPH NODES (see comment).

B. SURGICAL RESECTION MARGINS ARE BENIGN.

C. BACKGROUND LUNG WITH EMPHYSEMATOUS CHANGE AND RESPIRATORY BRONCHIOLITIS.

COMMENT:

The pathologic staging of this tumor is challenging. We are aware of the patient's CT guided FNA of the right upper lobe that was positive for non-small cell carcinoma, favor squamous cell carcinoma. It is uncertain whether tumor in the current specimen and tumor in the right upper lobe represent two independent primaries or a metastases. If these two tumors represent an independent primaries then the current tumor would be staged as T3N0. If the tumor in the right upper lobe represents a metastasis of the tumor in the left upper lobe then the stage would be T3 N0 M1a. Clinical correlation is suggested.

Source: NCI Genomic Data Commons file 2d60cabe-d629-45f9-8642-bd02eeb34800 (TCGA-34-8455.85247B02-2995-4CC7-9238-387BDA38DCEE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).